Somatic mutation profile of tumor specimen MP2PRT-PAUGEE-TBP1-A (aliquot MP2PRT-PAUGEE-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUGEE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,210 days).
Specimen MP2PRT-PAUGEE-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73ea05ce-17a2-47e6-baf1-f1f0081cc616.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGEE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGEE-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2732d1ef-125e-4831-b864-70924037ddc1

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Intron 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 24/223 reads (11%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- FLT3 | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1057520022, COSV54065509, COSV54077224; ClinVar: likely pathogenic; called by muse, mutect2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 26/390 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2
- AL354761.1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 25/329 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1190128328; called by muse, mutect2
- CARD14 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 104/322 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747854314, CM161584, COSV60122924; called by muse, mutect2, varscan2
- FAT3 | c.1033C>A p.L345I | Missense Mutation (SNP) | VAF 61/370 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV53189523; called by muse, mutect2, varscan2
- KDR | c.1724G>T p.R575I | Missense Mutation (SNP) | VAF 86/451 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs754856383, COSV55779016; called by muse, mutect2, varscan2
- MYH6 | c.5035C>T p.R1679C | Missense Mutation (SNP) | VAF 30/802 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs921540558, COSV62448362; called by muse, mutect2
- PSMA5 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99600579; called by muse, mutect2, varscan2
- SALL3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 159/942 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.353); catalogued as COSV73306219; called by muse, mutect2, varscan2
- TOGARAM1 | c.4121G>A p.R1374H | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754443483; called by muse, mutect2, varscan2
- ACSM2B | c.387A>C p.A129= | Splice Region (SNP) | VAF 30/390 reads (8%) | called by muse, mutect2
- BAHCC1 | c.3728C>G p.A1243G | Missense Mutation (SNP) | VAF 103/688 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHD4 | c.3508C>T p.R1170C (on ENST00000357008 / NM_001363606.2; = p.R1183C on NM_001273.5) | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYCN | c.1301A>G p.Q434R | Missense Mutation (SNP) | VAF 136/329 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- TRO | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 162/427 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- VSTM2A | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- ZNF233 | c.1175G>A p.S392N | Missense Mutation (SNP) | VAF 129/314 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY2 | c.435C>T p.F145= | Silent (SNP) | VAF 107/269 reads (40%) | catalogued as rs765777716, COSV57869101; called by muse, mutect2, varscan2
- CGRRF1 | c.534C>T p.T178= | Silent (SNP) | VAF 24/376 reads (6%) | called by muse, mutect2
- MUC6 | c.618G>A p.L206= | Silent (SNP) | VAF 109/621 reads (18%) | called by muse, mutect2, varscan2
- MYO16 | c.4296C>T p.Y1432= | Silent (SNP) | VAF 47/647 reads (7%) | catalogued as rs1430190086; called by muse, mutect2
- SHANK1 | c.6267G>A p.P2089= | Silent (SNP) | VAF 208/493 reads (42%) | catalogued as rs370010826; called by muse, mutect2, varscan2
- ZNF236 | c.1461C>T p.C487= | Silent (SNP) | VAF 121/654 reads (19%) | catalogued as rs1293239248, COSV53491077; called by muse, mutect2, varscan2
- GRM1 | c.2661-7272C>T | Intron (SNP) | VAF 257/428 reads (60%) | catalogued as rs745788064, COSV51202557, COSV99268134; called by muse, mutect2, varscan2
